Somatic mutation profile of tumor specimen TCGA-CR-7372-01A (aliquot TCGA-CR-7372-01A-11D-2012-08) from TCGA case TCGA-CR-7372, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 45.5 years (16,610 days).
Specimen TCGA-CR-7372-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9ca1a16-b365-4200-9ea1-dbc010f3b615.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7372-10A (Blood Derived Normal), aliquot TCGA-CR-7372-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c753b6f3-18f0-4858-89af-399be21ee4fc

The open-access MAF lists 52 somatic variants for this specimen: 40 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 10, Nonsense Mutation 5, Intron 2, In Frame Del 2, Frame Shift Del 2, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALCAM | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748880766, COSV60251651; called by mutect2, varscan2
- AP1G1 | c.1367T>C p.V456A | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.262); catalogued as COSV100250704; called by muse, mutect2, varscan2
- CDC23 | c.226A>T p.I76F | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV101203001; called by muse, mutect2, varscan2
- CNOT1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as COSV100409699; called by muse, mutect2, varscan2
- CSMD3 | c.3583G>A p.G1195R (on ENST00000297405 / NM_001363185.1; = p.G1091R on NM_052900.3) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52231204; called by muse, mutect2, varscan2
- DISP1 | c.2270C>A p.S757* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as rs754723527, COSV52664251, COSV99450250, COSV99451560; called by muse, mutect2, varscan2
- DNAH17 | c.3256C>T p.R1086W | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs374429842; called by muse, mutect2, varscan2
- DSC2 | c.1969G>A p.G657S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV99199741; called by muse, mutect2, varscan2
- DUOX1 | c.2344G>A p.D782N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as rs200102941, COSV58480965; called by muse, mutect2
- GRIP1 | c.2285G>T p.S762I (on ENST00000359742 / NM_001379345.1; = p.S710I on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV99670222; called by muse, mutect2, varscan2
- GTF2E1 | c.429G>T p.Q143H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV99382050; called by muse, mutect2, varscan2
- HS3ST5 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | catalogued as COSV100451126, COSV57135444; called by muse, mutect2, varscan2
- IPO7 | c.1066C>A p.P356T | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as rs1348532318, COSV100797829, COSV63352543; called by mutect2, varscan2
- KIAA1217 | c.5375C>T p.P1792L | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs993778827, COSV100286933; called by muse, mutect2, varscan2
- KIF1A | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57483567; called by muse, mutect2, varscan2
- LRP1B | c.12477A>C p.K4159N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.273); catalogued as COSV101258210; called by muse, mutect2, varscan2
- MAP1A | c.2087G>T p.R696L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV100288949; called by muse, mutect2, varscan2
- NALCN | c.4634G>A p.R1545Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99216458; called by muse, mutect2, varscan2
- OGDH | c.2170G>A p.G724S | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV99759264; called by muse, mutect2, varscan2
- PRKAR1B | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100816765, COSV64318171; called by muse, mutect2, varscan2
- PTPN3 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs746441964, COSV99356035; called by muse, mutect2, varscan2
- PTPRC | c.3559G>T p.E1187* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as COSV100722844; called by muse, mutect2, varscan2
- PTPRZ1 | c.6151A>T p.K2051* | Nonsense Mutation (SNP) | VAF 30/96 reads (31%) | catalogued as COSV101100497; called by muse, mutect2, varscan2
- PURA | c.590A>T p.E197V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100495763; called by muse, mutect2, varscan2
- SEC14L5 | c.1778G>T p.C593F | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.609); catalogued as COSV99229197; called by muse, mutect2, varscan2
- SLC5A1 | c.1545C>A p.S515R | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV99833589; called by muse, mutect2, varscan2
- SRSF7 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100492720; called by muse, mutect2
- STEAP4 | c.120G>T p.Q40H | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV100112646; called by muse, mutect2, varscan2
- TNRC18 | c.3742C>A p.Q1248K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.01); catalogued as COSV101269788; called by muse, mutect2, varscan2
- TTLL11 | c.1486G>A p.V496I | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.188); catalogued as COSV100389044, COSV58645685; called by muse, mutect2, varscan2
- UBE2S | c.262G>T p.V88L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99198782; called by muse, mutect2
- ZFHX4 | c.3133T>C p.C1045R | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.12); catalogued as rs749259046, COSV99265240; called by muse, mutect2, varscan2
- ZNF112 | c.1807C>A p.H603N (on ENST00000337401 / NM_001083335.2; = p.H597N on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100496051; called by muse, mutect2, varscan2
- ZNF473 | c.2281C>T p.Q761* | Nonsense Mutation (SNP) | VAF 14/104 reads (13%) | catalogued as COSV99568976; called by muse, mutect2
- ZNF792 | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 79/198 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV101289725; called by muse, mutect2, varscan2
- DNAJB14 | c.1075_1086del p.D359_S362del | In Frame Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel
- H1-4 | c.189_191del p.K64del | In Frame Del (DEL) | VAF 12/57 reads (21%) | called by mutect2, pindel, varscan2
- MTO1 | c.325_326dup p.H110Yfs*6 | Frame Shift Ins (INS) | VAF 19/102 reads (19%) | called by mutect2, pindel, varscan2
- NUP160 | c.3882_3903del p.Y1295Rfs*9 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel
- TP53 | c.234_235del p.A79Sfs*69 | Frame Shift Del (DEL) | VAF 89/169 reads (53%) | called by mutect2, pindel*, varscan2*
- ALS2CL | c.483C>T p.H161= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs752360050, COSV100015191; called by muse, mutect2, varscan2
- CAMK2D | c.348T>C p.C116= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99594427; called by muse, mutect2, varscan2
- DTNA | c.1626A>G p.L542= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV99313837; called by muse, mutect2, varscan2
- KCNK9 | c.654G>A p.P218= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as rs763076662, COSV57278769; called by muse, mutect2, varscan2
- PKHD1L1 | c.8148G>T p.L2716= | Silent (SNP) | VAF 46/165 reads (28%) | catalogued as COSV101006577; called by muse, mutect2, varscan2
- POLE | c.5523C>T p.L1841= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs754895008, COSV100267521; called by muse, mutect2, varscan2
- PRB4 | c.174A>G p.Q58= | Silent (SNP) | VAF 99/421 reads (24%) | catalogued as COSV99686702; called by muse, varscan2
- TDRD1 | c.684G>A p.E228= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99314839; called by muse, mutect2, varscan2
- TNRC18 | c.3741G>A p.V1247= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV101269789; called by muse, mutect2, varscan2
- UNC13C | c.3312G>A p.T1104= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as rs764967388, COSV99520544; called by muse, mutect2, varscan2
- CADM2 | c.62-75551C>A | Intron (SNP) | VAF 12/74 reads (16%) | catalogued as COSV67401864; called by mutect2, varscan2
- ESRRB | c.1296+450G>A | Intron (SNP) | VAF 13/46 reads (28%) | catalogued as rs373526001, COSV55067888; called by muse, mutect2, varscan2
